Somatic mutation profile of tumor specimen ALCH-B0HO-TTP1-A (aliquot ALCH-B0HO-TTP1-A-1-0-D-A714-36) from ALCHEMIST case ALCH-B0HO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.8 years (26,224 days).
Specimen ALCH-B0HO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2b58865-258e-4d03-a18f-230b5a3b2726.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0HO-NB1-A (Blood Derived Normal), aliquot ALCH-B0HO-NB1-A-1-0-D-A714-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf0693a2-51e1-44cb-9012-e375d2448440

The open-access MAF lists 67 somatic variants for this specimen: 46 protein-altering or splice-affecting, 16 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 16, Nonsense Mutation 3, 5'Flank 2, 3'UTR 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 92/656 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 17/207 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs776846119, COSV59205460, COSV59217320; called by muse, mutect2
- CACNA1E | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1273665569; called by muse, mutect2
- CDC73 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 26/632 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV100813950; called by muse, mutect2
- COL5A2 | c.3379C>T p.R1127C | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886055354, COSV66407318; ClinVar: uncertain significance; called by muse, mutect2
- CRYBG3 | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV99476843; called by muse, mutect2
- DUOX2 | c.2143G>C p.D715H | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV101199584; called by muse, mutect2
- EIF2B2 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 29/504 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs751159755, COSV99837699; called by muse, mutect2
- ERVW-1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.295); catalogued as rs773801539, COSV71259650; called by muse, mutect2
- HPSE | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV60986125; called by muse, mutect2
- LARP4B | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1163457856; called by muse, mutect2
- MAN1A2 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 16/374 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs1382492659; called by muse, mutect2
- NFASC | c.2619G>C p.Q873H (on ENST00000339876 / NM_001378329.1; = p.Q976H on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV58363332; called by muse, mutect2
- NMT1 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs1384334634; called by muse, mutect2
- RASGRF2 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV54122528; called by muse, mutect2, varscan2
- RRM2 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1338683193, COSV100459819; called by muse, mutect2
- TP53TG3D | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 45/618 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.682); catalogued as rs768450898; called by muse, mutect2
- TRPM8 | c.2683C>T p.R895C | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470605742, COSV61220763; called by muse, mutect2
- TTC37 | c.1708C>T p.R570* | Nonsense Mutation (SNP) | VAF 25/413 reads (6%) | catalogued as rs768215813, CM130215; called by muse, mutect2
- USP47 | c.1251G>C p.M417I (on ENST00000399455 / NM_001372095.1; = p.M329I on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV60467367; called by muse, mutect2
- AFP | c.1468A>G p.M490V | Missense Mutation (SNP) | VAF 18/340 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- APOB | c.11449G>C p.E3817Q | Missense Mutation (SNP) | VAF 12/308 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.139); called by muse, mutect2
- BEND7 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 8/184 reads (4%) | called by muse, mutect2
- CHD2 | c.1156G>T p.V386L | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.103); called by muse, mutect2
- DHFR | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.518); called by muse, mutect2
- EPHA6 | c.2336G>T p.G779V (on ENST00000389672 / NM_001080448.3; = p.G171V on NM_173655.4) | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GBF1 | c.277C>A p.L93M | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GJB6 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 26/440 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- H2AZ2 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 19/472 reads (4%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.478); called by muse, mutect2
- H2BU1 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- HELB | c.3200A>C p.N1067T | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, mutect2
- HPF1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2
- HSPA14 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.047); called by muse, mutect2
- KCNK9 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MFAP1 | c.1063G>A p.V355I | Missense Mutation (SNP) | VAF 7/198 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.401); called by muse, mutect2
- NOS1 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR7C1 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 10/267 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PLCE1 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 19/559 reads (3%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2
- RNF123 | c.2453T>G p.L818R | Missense Mutation (SNP) | VAF 15/262 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- STK38 | c.722A>T p.H241L | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- TINAG | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- TRIM66 | c.3145A>C p.K1049Q | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TTLL6 | c.449T>A p.L150Q | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.23455G>C p.E7819Q (on ENST00000591111; = p.E6892Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/379 reads (4%) | PolyPhen benign (0.037); called by muse, mutect2
- YLPM1 | c.5888A>G p.D1963G | Missense Mutation (SNP) | VAF 13/315 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ZNF282 | c.687G>C p.E229D | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.396); called by muse, mutect2
- CEP192 | c.2691T>G p.A897= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- CEP20 | c.375A>G p.A125= | Silent (SNP) | VAF 20/276 reads (7%) | catalogued as rs776406271; called by muse, mutect2
- CHAT | c.1890G>T p.L630= | Silent (SNP) | VAF 27/525 reads (5%) | called by muse, mutect2
- CRTAP | c.390C>G p.R130= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- DCAF8L2 | c.684C>T p.V228= | Silent (SNP) | VAF 10/194 reads (5%) | catalogued as rs1164637843; called by muse, mutect2
- GLS | c.285G>A p.S95= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs1049421722; called by muse, mutect2, varscan2
- GPR35 | c.153G>A p.Q51= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as rs893438888; called by muse, mutect2
- GRIN2B | c.4371T>A p.P1457= | Silent (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2, varscan2
- GRK1 | c.1641C>T p.I547= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1261004739; called by muse, mutect2
- INPP5F | c.1776G>A p.Q592= | Silent (SNP) | VAF 20/558 reads (4%) | called by muse, mutect2
- KCNQ2 | c.804C>G p.L268= | Silent (SNP) | VAF 22/484 reads (5%) | called by muse, mutect2
- KRT1 | c.1785C>T p.G595= | Silent (SNP) | VAF 40/202 reads (20%) | catalogued as COSV99359041; called by muse, varscan2
- MYO1A | c.1722C>T p.L574= | Silent (SNP) | VAF 17/513 reads (3%) | catalogued as rs1309143468; called by muse, mutect2
- SEPHS2 | c.378G>C p.L126= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- TBX21 | c.729G>A p.K243= | Silent (SNP) | VAF 21/224 reads (9%) | called by muse, mutect2
- XIRP2 | c.6975C>G p.L2325= (on ENST00000628543; = p.L2500= on NM_152381.6) | Silent (SNP) | VAF 21/288 reads (7%) | called by muse, mutect2
- C14orf39 | chr14:60433383 T>A | 3'Flank (SNP) | VAF 14/255 reads (5%) | called by muse, mutect2
- GUCY1A2 | c.1206+2776C>T | Intron (SNP) | VAF 16/297 reads (5%) | catalogued as rs1470629551, COSV104388828; called by muse, mutect2
- POLR1H | c.*2C>T | 3'UTR (SNP) | VAF 16/225 reads (7%) | called by muse, mutect2
- TRAPPC9 | chr8:140458330 G>T | 5'Flank (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- TRAPPC9 | chr8:140458331 G>T | 5'Flank (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
